Somatic mutation profile of tumor specimen TCGA-AF-6136-01A (aliquot TCGA-AF-6136-01A-11D-1826-10) from TCGA case TCGA-AF-6136, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.5 years (26,490 days).
Specimen TCGA-AF-6136-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ecc11b5-f72b-4cc8-99a3-2b6537511714.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-6136-10A (Blood Derived Normal), aliquot TCGA-AF-6136-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff5fc89d-9d23-406c-a518-5c4970493cbc

The open-access MAF lists 131 somatic variants for this specimen: 92 protein-altering or splice-affecting, 38 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 38, Nonsense Mutation 6, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 51/96 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs147652549; called by muse, mutect2, varscan2
- ADGRL1 | c.937C>T p.R313C (on ENST00000340736 / NM_001008701.3; = p.R308C on NM_014921.5) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243120331, COSV61564696; called by muse, mutect2, varscan2
- ALK | c.3625C>T p.R1209* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs769449619, COSV66562973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.1258T>C p.F420L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.339); catalogued as COSV66568202; called by muse, mutect2, varscan2
- ANKRD50 | c.1738A>C p.T580P | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV72385552; called by muse, mutect2, varscan2
- ARID1B | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs752863054, COSV51661590; called by muse, mutect2, varscan2
- BAZ2B | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.247); catalogued as COSV58600741; called by muse, mutect2, varscan2
- C14orf39 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs776214261, COSV58781935, COSV58783792; called by muse, mutect2, varscan2
- CBFA2T3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs760610315, COSV51925320; called by muse, mutect2, varscan2
- CCN5 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs759003113, COSV51937301; called by muse, mutect2, varscan2
- CDH23 | c.6511C>T p.R2171C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs781698111, CD084050, CM078753, COSV56480429; called by mutect2, varscan2
- CDH4 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs373320390; called by muse, mutect2, varscan2
- CEP170 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63732156; called by muse, mutect2, varscan2
- CIITA | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs374703179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT4 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs371838377; called by muse, mutect2, varscan2
- CNTNAP2 | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs143879959, COSV62265209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.6728C>T p.P2243L | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs544059289, COSV64715627, COSV64727491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUEDC1 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV64226404; called by muse, mutect2, varscan2
- CYLC1 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 101/588 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV61412125; called by muse, mutect2, varscan2
- DAPK1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 96/177 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs761997264, COSV63787377; called by muse, mutect2, varscan2
- DNAH11 | c.4095+5G>A | Splice Region (SNP) | VAF 27/92 reads (29%) | catalogued as COSV100176161; called by muse, mutect2, varscan2
- DOCK11 | c.5684T>C p.F1895S | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52238938; called by muse, mutect2, varscan2
- DYNC2H1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs757134411, COSV62094130; called by muse, mutect2, varscan2
- FAT1 | c.1637C>G p.P546R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373737710, COSV101499572, COSV71673889, COSV71676702; called by muse, mutect2, varscan2
- FGA | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs769422386, COSV57396069; called by muse, mutect2, varscan2
- FGF14 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV65943692; called by muse, mutect2, varscan2
- FLRT2 | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV58141428; called by muse, mutect2, varscan2
- FLT1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 114/179 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374335323, COSV56723065, COSV99167652; called by muse, mutect2, varscan2
- FPR1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs140083445, COSV59052249, COSV59052753; called by muse, mutect2, varscan2
- FRMPD1 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764260619, COSV66700386; called by muse, mutect2, varscan2
- GPR174 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52132526; called by muse, mutect2, varscan2
- GRHL3 | c.1060G>A p.V354I (on ENST00000350501 / NM_198174.3; = p.V359I on NM_021180.3) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs375437963; called by muse, mutect2, varscan2
- HDHD3 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 30/54 reads (56%) | catalogued as rs1564353800, COSV53057154; called by muse, mutect2, varscan2
- HECTD4 | c.8402T>G p.V2801G | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV66391982; called by muse, mutect2, varscan2
- HK3 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756923182, COSV52837972; called by muse, mutect2, varscan2
- HYDIN | c.6440G>A p.R2147H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs558300717, COSV99991659; called by muse, mutect2, varscan2
- IFNA10 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 105/450 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV53331125; called by muse, varscan2
- IFNGR1 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs146424575; called by muse, mutect2, varscan2
- IGHV3-20 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs782747493; called by muse, mutect2, varscan2
- IL6 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV51732692; called by muse, mutect2, varscan2
- KCNJ6 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55714218; called by muse, mutect2, varscan2
- KIAA0586 | c.527C>G p.A176G (on ENST00000619416 / NM_001244190.2; = p.A191G on NM_014749.5) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54175762; called by muse, mutect2
- KIF1A | c.4573G>A p.G1525S (on ENST00000320389 / NM_001379639.1; = p.G1517S on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs777997857, COSV100239471; called by muse, mutect2, varscan2
- KLK14 | c.465C>T p.I155= | Splice Region (SNP) | VAF 10/38 reads (26%) | catalogued as rs373226064; called by muse, mutect2, varscan2
- KMT2D | c.6397G>A p.A2133T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs781460562, COSV56439361; called by muse, mutect2, varscan2
- KRTAP20-2 | c.12del p.Y4* | Frame Shift Del (DEL) | VAF 70/277 reads (25%) | catalogued as COSV58183305; called by mutect2, pindel, varscan2
- LIFR | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs749557070, COSV54684264; called by muse, mutect2, varscan2
- LRRC7 | c.2683G>A p.A895T (on ENST00000651989 / NM_001370785.2; = p.A862T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1455950577, COSV50456565, COSV50534238; called by muse, mutect2, varscan2
- MAMLD1 | c.1913G>C p.R638T | Missense Mutation (SNP) | VAF 145/432 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV53374821; called by muse, mutect2, varscan2
- MAN2C1 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs754290709, COSV51228822; called by muse, mutect2, varscan2
- MAOB | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 52/147 reads (35%) | catalogued as COSV65205276; called by muse, mutect2, varscan2
- MEX3A | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV68479091; called by muse, mutect2, varscan2
- MPO | c.1853G>A p.G618D | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.644); catalogued as COSV51858749; called by muse, mutect2, varscan2
- MXRA5 | c.5878G>A p.V1960I | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV54234921; called by muse, mutect2, varscan2
- NME8 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV52250215, COSV52256409; called by muse, mutect2, varscan2
- NPR1 | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV64117370, COSV64117607; called by muse, mutect2, varscan2
- OCRL | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV63980900; called by muse, mutect2, varscan2
- PCDH9 | c.2929T>C p.C977R | Missense Mutation (SNP) | VAF 121/189 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV60550218; called by muse, mutect2, varscan2
- PDE10A | c.2097G>T p.E699D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63096556; called by muse, mutect2, varscan2
- PLSCR5 | c.566T>G p.I189S | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV71648931; called by muse, mutect2, varscan2
- PLXNB3 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781882423, COSV62797330; called by muse, mutect2, varscan2
- PPM1A | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs746894375, COSV57786825; called by muse, mutect2, varscan2
- PROX1 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs745534059, COSV54778978; called by muse, mutect2, varscan2
- PRPS1L1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV101552954, COSV72649893; called by muse, mutect2, varscan2
- PTPN23 | c.3400C>T p.P1134S | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs1304436832, COSV55544583; called by muse, mutect2, varscan2
- RFC1 | c.2558G>A p.R853Q (on ENST00000381897 / NM_001363496.2; = p.R852Q on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762772857, COSV62899621, COSV62901073; called by muse, mutect2, varscan2
- RHBDL3 | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52186166; called by muse, mutect2, varscan2
- RPS6KC1 | c.1840G>T p.G614* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV65299288; called by muse, mutect2, varscan2
- RYR2 | c.10529G>A p.R3510H | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs375947003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAP | c.2971-1G>T p.X991_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | catalogued as COSV55544589; called by muse, mutect2, varscan2
- SCD5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs762891080, COSV56726239; called by muse, mutect2, varscan2
- SEC16B | c.2320C>A p.Q774K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57625579; called by muse, mutect2, varscan2
- SLC26A3 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs776888978, COSV60639399; called by muse, mutect2, varscan2
- SLC30A1 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV65361017; called by muse, mutect2, varscan2
- SMAD4 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688293, COSV99048762; called by muse, mutect2
- ST8SIA6 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765868275, COSV66468310; called by muse, mutect2, varscan2
- TCF4 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs1420909531, COSV61890124; called by muse, mutect2, varscan2
- TDRD6 | c.2750dup p.N917Kfs*15 | Frame Shift Ins (INS) | VAF 42/93 reads (45%) | catalogued as rs765467808; called by mutect2, varscan2
- TLX1 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV64622312; called by muse, mutect2, varscan2
- TMEM131L | c.1414T>C p.F472L | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV53644400; called by muse, mutect2, varscan2
- TP53 | c.279_280dup p.S94Cfs*30 | Frame Shift Ins (INS) | VAF 43/95 reads (45%) | catalogued as COSV53120927; called by mutect2, pindel, varscan2
- TP53TG5 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140811424; called by muse, mutect2, varscan2
- TRIM59 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778384623, COSV59087297; called by muse, varscan2
- TRIM9 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as rs751149890, COSV53615744; called by muse, mutect2
- TRPC6 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as COSV60254696; called by muse, mutect2, varscan2
- TTN | c.31332G>T p.E10444D (on ENST00000591111; = p.E9517D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/211 reads (22%) | PolyPhen probably damaging (0.953); catalogued as COSV60059273; called by muse, mutect2, varscan2
- TUBA3E | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as rs143099002; called by muse, mutect2, varscan2
- VWA2 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.112); catalogued as rs376331052; called by muse, mutect2, varscan2
- ZNF507 | c.2326C>A p.H776N | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943637575, COSV61331270; called by muse, mutect2, varscan2
- ZNF800 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV56175647; called by muse, mutect2, varscan2
- AXIN2 | c.331del p.W111Gfs*10 | Frame Shift Del (DEL) | VAF 46/99 reads (46%) | called by mutect2, pindel, varscan2
- ALX3 | c.471C>A p.R157= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV100873857; called by muse, mutect2, varscan2
- ASXL1 | c.4395A>G p.K1465= | Silent (SNP) | VAF 65/161 reads (40%) | catalogued as COSV100037291; called by muse, mutect2, varscan2
- ATRNL1 | c.3618G>A p.V1206= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV58088329; called by muse, mutect2, varscan2
- BCORL1 | c.3459T>C p.S1153= | Silent (SNP) | VAF 57/148 reads (39%) | catalogued as COSV54396268; called by muse, mutect2, varscan2
- BEND4 | c.627C>T p.N209= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as rs574971489, COSV72468915; called by muse, mutect2, varscan2
- BIN1 | c.1281C>T p.A427= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as rs373834859; called by muse, mutect2, varscan2
- CDH13 | c.2070C>T p.N690= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs374049780; called by muse, mutect2, varscan2
- CHMP3 | c.192C>T p.A64= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV99806454; called by muse, mutect2, varscan2
- CHPF | c.1338G>A p.Q446= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV60534729; called by muse, mutect2, varscan2
- COL4A2 | c.3075G>T p.L1025= | Silent (SNP) | VAF 78/96 reads (81%) | catalogued as COSV64628257; called by muse, mutect2, varscan2
- CRY1 | c.1626C>T p.G542= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs1260357274, COSV50482786; called by muse, mutect2, varscan2
- CSNK1A1L | c.897G>A p.T299= | Silent (SNP) | VAF 252/406 reads (62%) | catalogued as rs781264924, COSV65789310; called by muse, mutect2, varscan2
- DEF8 | c.1323C>T p.C441= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs751104438, COSV51919114; called by muse, mutect2, varscan2
- ELMO1 | c.45G>A p.P15= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs759462213, COSV60294967, COSV60303790; called by muse, mutect2, varscan2
- FBLN2 | c.2808G>A p.A936= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs748718491, COSV55484405; called by muse, mutect2, varscan2
- IBSP | c.486C>T p.N162= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV56894518; called by muse, mutect2, varscan2
- ITIH2 | c.1971C>T p.Y657= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs376027605; called by muse, mutect2, varscan2
- JRK | c.1287G>A p.P429= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs369974690, COSV70629846; called by muse, mutect2, varscan2
- KCNH7 | c.3486C>T p.Y1162= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as rs748046524, COSV59791936; called by muse, mutect2, varscan2
- KRTAP19-5 | c.204C>T p.F68= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100478358; called by muse, mutect2, varscan2
- LHFPL5 | c.150C>T p.I50= | Silent (SNP) | VAF 37/192 reads (19%) | catalogued as rs200638980, COSV64177752; called by muse, mutect2, varscan2
- LIFR | c.2481G>T p.V827= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV54690028; called by muse, mutect2, varscan2
- LPA | c.3264G>T p.R1088= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV60301847; called by muse, mutect2, varscan2
- MAF | c.315G>T p.A105= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs754156981, COSV58153874; called by muse, mutect2, varscan2
- ODAPH | c.87G>A p.T29= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs779985232, COSV61141208; called by muse, mutect2, varscan2
- OR5W2 | c.300A>G p.Q100= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV100747515; called by muse, mutect2, varscan2
- PCDH17 | c.798C>T p.N266= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs1172909972, COSV64974101; called by muse, mutect2, varscan2
- PIGK | c.357G>A p.V119= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV63062199; called by muse, mutect2, varscan2
- PKHD1 | c.8886C>T p.D2962= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs138464473, COSV61875280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMBP2 | c.2103C>T p.Y701= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs574899300, COSV55472368; called by mutect2, varscan2
- SIGLECL1 | c.453G>A p.A151= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs369648100; called by muse, mutect2, varscan2
- SRL | c.69G>A p.T23= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs369887184; called by muse, mutect2, varscan2
- STC1 | c.453G>T p.L151= | Silent (SNP) | VAF 70/106 reads (66%) | catalogued as COSV51688445; called by muse, mutect2, varscan2
- SUGT1 | c.795G>A p.T265= (on ENST00000343788 / NM_001130912.3; = p.T233= on NM_006704.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/202 reads (48%) | catalogued as rs535411991, COSV59421907; called by muse, mutect2, varscan2
- WDR49 | c.1095C>T p.D365= (on ENST00000308378 / NM_001366158.1; = p.D706= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV57704461, COSV57711572; called by muse, mutect2, varscan2
- WNT5B | c.873C>T p.N291= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs754560999, COSV60197490; called by muse, mutect2, varscan2
- ZNF536 | c.81C>T p.N27= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs1346301084, COSV62824162; called by muse, mutect2, varscan2
- ZNF536 | c.489C>T p.C163= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1427014287, COSV62818202; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928578 C>T | 3'Flank (SNP) | VAF 18/68 reads (26%) | catalogued as rs752264285, COSV60485841; called by muse, mutect2, varscan2
